Surgical pathology report (de-identified scan), TCGA case TCGA-B8-5550, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-5550-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Surgical Pathology Report

Diagnosis:

FSA: Kidney mass, right, biopsy

- Positive for renal cell carcinoma, conventional clear cell type.

B: Kidney, right, nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, conventional clear cell type

Sarcomatoid features: absent

Histologic grade (if applicable): Fuhrman nuclear grade 3 (of 4)

Tumor size (greatest dimension): 10.1 cm

Tumor focality: focal

Extent of invasion:

Capsular invasion/perirenal adipose tissue: not involved

Gerota's fascia: not involved

Renal sinus: not involved

Renal vein: involved

Ureter: not involved

Lymphatic (small vessel): not involved

Surgical margins:

Peri-nephric soft tissue: not involved

Renal vein (nephrectomy): involved

Ureter (nephrectomy): not involved

Adrenal gland: absent

Lymph nodes: separately submitted, spec C: no metastatic carcinoma identified (0/3)

Other significant findings: benign, mild nephrosclerosis

AJCC Stage: pT3a pN0 pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

C: Right hilar lymph nodes, removal

- No metastatic carcinoma identified (0/3).

Intraoperative Consult Diagnosis:

An intraoperative consultation is requested by

FSA1: Right kidney mass, biopsy

- Renal cell carcinoma

Frozen Section Pathologist:

Clinical History:

a right renal mass.

Gross Description:

Received are three appropriately labeled containers.

[page 2 of 3]
Container A: Received fresh for frozen section is a 2 x 0.9 x 0.6 cm red/tan soft tissue fragment which is totally submitted as FSA1, NTR.

Container B:

Specimen fixation: formalin

Type of specimen: radical nephrectomy

Side of specimen: right

Size and weight of specimen: 850 grams; total specimen measures 18 x 10 x 10 cm; The kidney measures 12.5 x 8.0 x 5.1 cm.

Orientation: The external surface of the specimen has been inked blue after the specimen was bivalved in the OR.

Presence/absence of adrenal gland: absent

Tumor description/site: The tumor has a rounded, yet infiltrative and lobular appearance. The tumor has a yellow/tan color with scattered areas of necrosis and hemorrhage. Sections of the tumor demonstrate prominent fibrosis. The tumor has a firm, fibrous texture.

Tumor size: 10.1 x 8.1 x 5.1 cm; The tumor involves the superior and inferior halves of the kidney

Presence/absence of multicentricity: absent, the tumor is unifocal

Confinement/non-confinement to the kidney: confined

Extent of invasion:

Perirenal adipose tissue: tumor grossly does not involve

Gerota's fascia: grossly does not involve

Renal vein: tumor grossly involves renal vein

Ureter: tumor grossly does not involve ureter

Other organs: tumor appears to invade the renal pelvis

Surgical margins:

Perirenal adipose tissue: negative

Renal vein: negative

Renal artery: negative

Ureter: negative

Description of kidney away from tumor: unremarkable

Lymph nodes (hilar): see Specimen C

Other significant findings: none

Tissue submitted for special investigations: tumor is submitted to Tissue Procurement

Digital photograph taken: no

Block summary:

B1 - vascular and ureteral margins

B2 - tumor involving urothelium, tumor adjacent to normal parenchyma

B3 - tumor expanding capsule, ?fat involvement

B4 - tumor closest to inked margin

B5 - additional representative tumor

B6 - kidney away from tumor

B7 - tumor adjacent to hilar fat

B8,B9 - ?vascular and ureteral involvement by tumor

B10- Additional ureteral margin

B11 ureter and kidney

B12 tumor at renal pelvis

Container C is additionally labeled "right hilar lymph node." The specimen consists of an aggregate of fibrofatty tissue fragments measuring 4.1 x 2.5 x 1.2 cm. Three lymph node candidates are isolated from the tissue fragments. The lymph node candidates range in size from 5 mm to 1.2 cm in greatest dimension.

[page 3 of 3]
Block summary:

C1 - two lymph node candidates, one inked blue and bisected

C2 - one lymph node candidate, fat remains

Grossing Pathologist

Light Microscopy:

Light microscopic examination is performed by [REDACTED] The FS diagnosis is confirmed.

Signature

[REDACTED]

Source: NCI Genomic Data Commons file cdad82b1-57b3-4532-84b9-fa224851c1c8 (TCGA-B8-5550.182F3409-7456-4718-856A-BEDA10C12E8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).